Somatic mutation profile of tumor specimen d01714eb-22bf-4ad7-95d9-f95bdf (aliquot d01714eb-22bf-4ad7-95d9-f95bdf_D6) from CPTAC case 05BR044, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.7 years (22,903 days).
Specimen d01714eb-22bf-4ad7-95d9-f95bdf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b2ffe46-ef88-473c-a651-746488046a9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ccd93955-378a-48ae-8ed2-07ee76 (Blood Derived Normal), aliquot ccd93955-378a-48ae-8ed2-07ee76_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f2d25f7-8d63-45d2-bac6-2c8fad0a80e0

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 5, Frame Shift Ins 3, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 83/206 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GART | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1569032075; called by muse, mutect2, varscan2
- NT5DC4 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs904701383; called by muse, mutect2, varscan2
- PCDH17 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 29/670 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64975650; called by muse, mutect2
- PRAME | c.1445T>G p.L482R | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101287092, COSV101287296; called by muse, mutect2, varscan2
- PRUNE2 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs755404522; called by muse, mutect2, varscan2
- RET | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 94/855 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs754598663, COSV60713724; called by muse, mutect2, varscan2
- SLC22A15 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.33); catalogued as rs767790243, COSV65678061; called by muse, mutect2, varscan2
- TACR3 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59201193, COSV59206050; called by muse, mutect2, varscan2
- TBPL2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs912768584; called by muse, mutect2, varscan2
- TMC6 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs551782028, COSV100130510; called by muse, mutect2
- ARC | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARHGAP39 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 76/302 reads (25%) | called by muse, mutect2, varscan2
- CD74 | c.38A>G p.Q13R | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CMYA5 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL11A2 | c.4010C>A p.A1337D (on ENST00000341947 / NM_080680.3; = p.A1230D on NM_080679.2) | Missense Mutation (SNP) | VAF 134/533 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- E2F6 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- FBXL16 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.283); called by muse, mutect2
- GPER1 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC11 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INF2 | c.877T>A p.S293T | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- KLHL7 | c.178G>T p.V60F (on ENST00000339077 / NM_001031710.3; = p.V12F on NM_018846.5) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LGI4 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.291); called by muse, mutect2
- MUC5AC | c.14375C>T p.P4792L | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC6 | c.6389C>T p.S2130L | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMUR1 | c.1196G>C p.C399S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA12 | c.2299A>T p.T767S | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA3 | c.2174T>C p.L725P | Missense Mutation (SNP) | VAF 40/886 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); called by muse, mutect2
- PKN1 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- POLQ | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- RFT1 | c.1081_1082insAGGA p.T361Kfs*5 | Frame Shift Ins (INS) | VAF 38/232 reads (16%) | called by pindel, varscan2
- RFT1 | c.1077_1078insCG p.G360Rfs*29 | Frame Shift Ins (INS) | VAF 45/249 reads (18%) | called by mutect2, varscan2*
- SERPINB7 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPHKAP | c.3138_3154del p.M1047Lfs*36 | Frame Shift Del (DEL) | VAF 40/299 reads (13%) | called by mutect2, pindel, varscan2
- TMEM54 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VASN | c.479_482dup p.L163Gfs*163 | Frame Shift Ins (INS) | VAF 62/385 reads (16%) | called by mutect2, pindel, varscan2
- ZNF268 | c.1492A>G p.K498E | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF638 | c.4031A>C p.E1344A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ACE | c.3879C>T p.H1293= | Silent (SNP) | VAF 34/770 reads (4%) | catalogued as rs1013454628; called by muse, mutect2
- AGPAT2 | c.336G>T p.P112= | Silent (SNP) | VAF 54/310 reads (17%) | catalogued as COSV100452078; called by mutect2, varscan2
- BTBD7 | c.1281T>C p.C427= | Silent (SNP) | VAF 83/264 reads (31%) | catalogued as rs755546316; called by muse, mutect2, varscan2
- C8orf48 | c.156G>C p.G52= | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- ERCC4 | c.66G>T p.L22= | Silent (SNP) | VAF 90/408 reads (22%) | called by muse, mutect2, varscan2
- FARP2 | c.318T>A p.I106= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- H1-4 | c.597T>C p.A199= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1188372612; called by muse, mutect2, varscan2
- MCM5 | c.732C>T p.H244= | Silent (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- MTRF1 | c.1197G>A p.R399= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101067601; called by muse, mutect2, varscan2
- TTN | c.41944A>C p.R13982= (on ENST00000591111; = p.R6558= on NM_003319.4) | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- AGAP1 | c.1051-30613G>T | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- CFAP54 | c.4547+804T>A | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- COG7 | c.2146+41G>A | Intron (SNP) | VAF 47/184 reads (26%) | called by muse, mutect2, varscan2
- L1CAM | c.-109+1900A>G | Intron (SNP) | VAF 61/365 reads (17%) | called by muse, mutect2, varscan2
- MAGEB16 | c.-29C>T | 5'UTR (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2, varscan2
- MXD4 | c.165-1042_165-1036del | Intron (DEL) | VAF 48/202 reads (24%) | called by mutect2, pindel*, varscan2
- PATZ1 | chr22:31347031 C>G | 5'Flank (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
